Surgical pathology report (de-identified scan), TCGA case TCGA-66-2769, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2769-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left upper lobe, among others

Clinical diagnosis and question

Squamous cell carcinoma, left upper lobe, asbestos.

REPORT ON FINDINGS**Macroscopy**

- 1.) Pleura (according to sample vessel received squamous epithelium): flat tissue measuring 1.5 x 0.8 cm, up to 0.2 cm thick, surface predominantly shiny and red in patches.
- 2.) Inflated, fixed resected left upper lobe measuring 21 x 10 x 6 cm, central bronchus resection plane located 0.5 cm proximal to the bifurcation of the lingular bronchus. At the hilus are 5 partly lesioned grayish-black nodes between 0.4 and 1.7 cm in size. The lateral region over segments 1 and 2 and also adjacent sections of S3 show an area of parietal pleura measuring 13 x 11.5 cm that is extensively adhesive in most parts, loosely attached in other parts and shows plate-like thickening up to 0.3 cm at the caudal margin in an area of max. 2 cm. At the upper margin of the adhesion zone are two interlinked costal segments 6 and 8.5 cm long, respectively, each clearly resected, and adhesive soft tissue up to 0.5 cm thick. Below the pleural adhesion is a soft to moderately firm, pale brown to whitish and centrally markedly soft tumor, max. 6 cm in size, with unclear demarcation and the main mass located in segment 2 and adjacent sections of S1 and S3, extending to the pleura in the region of the adhesion zone. Truncation of peripheral branches of B2 in the tumor. Section surfaces of the intercostal soft tissue at the area of site with the lung show a grayish-white area of 1.3 cm; costal segments do not show macroscopic infiltration by the tumor tissue. Tumor spread right up to the caudal margin of the adhesive part of the pleura. Dorsal pleura over segment 1 at the junction with segment 2 shows patchy whitish discoloration and thickening in an area of 6.5 cm, where there are isolated metal staples. Rest of parenchyma inconspicuous. At the bifurcation of the upper lobe bronchus are three grayish-black nodes between 1.6 and 2.1 cm. In the subpleural region of segment 3 is a 3 cm grayish-black node.
- 3.) Visceral pleura left lower lobe: nine flat or membranous specimens between 0.5 and 3.8 x 2 cm and up to 0.2 cm thick with a partly shiny, partly roughened or vaguely tubercular surface.
- 4.) Lobar LN (station 12) left: lingula: 2.2 cm lesioned grayish-black node or node part.
- 5.) Lobar LN (station 12) left lower lobe.: 0.5 cm lesioned grayish-black node.
- 6.) Interlobar LN (station 11) left: 0.5 cm lesioned grayish-black node with some surrounding tissue.
- 7.) Hilar LN (station 10) left: 1 cm lesioned grayish-black node.
- 8.) Paraesophageal LN (station 8) left: 0.8 cm grayish-black node.
- 9.) Subcarinal LN (station 7): 1.5 cm node with some surrounding tissue, containing further 0.1 cm node.
- 10.) Subaortic LN (aortopulmonary window) (station 5) left: 0.9 cm lesioned grayish-black node.
- 11.) Lobar LN (station 10) right: 1.5 cm lesioned grayish-black node or node.

Examined:

- 1.) Rapid section remains,
- 2.) 2 sections of tumor with remaining parenchyma, 3 sections with pleura in region of adhesion zone (1d ventral resection margin of pleural tissue color-marked), 2 sections of caudal margin of parietal pleura (color-marked), 2 sections of plate-like pleura thickening, S1/2 with whitish pleura, S2 dorsal, node at bifurcation of bronchus (partly halved, in 2i + j), subpleural nodes in S3 + central bronchus resection line and resection

[page 2 of 2]
margins of vessels, hilar nodes (2 larger ones multi-segmented + each separate in 2m + n, second-largest halved in 21), 2 sections of costal segments with grayish-white area,
3.) - 11.) All material (in 3. preparation lamellated, in 4., 10. + 11. nodes halved in each case, in 9. larger node multi-segmented, smaller node isolated),
27 blocks, partly Elastica-van Gieson, PAS, diastase-PAS, iron staining, decalcification.

Microscopy

Re 1.) Immediate intraoperative evaluation (): marked inflammation, blood pigment deposit, individual marked larger cells, but no evidence of carcinoma.

After paraffin embedding:

Description of histological and cytological findings omitted for capacity reasons.

EVALUATION

Primary diagnosis/diagnoses:

Locally advanced, peripheral bronchopulmonary, histologically poorly differentiated nonkeratinizing squamous cell carcinoma of the upper lobe of the left lung mainly located in S2. TNM classification according to this picture pT4 pN0 pMX R1, IIIB. C34.1 M8070/3.

Secondary diagnosis/diagnoses:

Pleural tissue with marked chronic inflammation, blood pigment deposit and fibrous thickening (sample 1.)). Extensive tumor necroses. Active chronic organizing pneumonia in the tumor environment. Moderate to marked active chronic peripheral bronchitis and bronchiolitis. Foci of fibrin-rich and chronic granulating visceral neuritis over S1. Hypocellular fibrosis zone of the adherent part of the parietal pleura (sample 2.)). Lymph nodes with uncharacteristic reactive lesions, anthracotic pigment deposits and sclerosis zones (samples 2.) and 4.) - 11.)).

Remark/addendum:

The tumor extends to the adherent part of the parietal pleura and the soft portions of the co-resected parts of the chest wall. With regard to the localization data, sample 3.) shows a discontinuous spread of the carcinoma within pleura enlarged by fibrosis and showing fibrinous chronic inflammation, although no conclusion can be drawn as to whether this is a visceral or parietal layer. The resection margins of bronchus and vessels of the main preparation, the costal segments of the chest wall tissue, the repeat resection material from the pleura in sample 1.) and all excised lymph nodes are tumor-free. The R1 category is explained by the fact that the tumor has spread focally as far as resection surface of the adherent part of the parietal pleura adjacent to the chest wall. No asbestos bodies are found in the prepared section planes, but much further-reaching investigations, especially dust analyses, are needed to determine the asbestos exposure of the lung.

Source: NCI Genomic Data Commons file 83d384cf-16b6-483d-83d6-61341c52426d (TCGA-66-2769.3A61E4A8-B574-49A2-BEA4-5479A1EFB1F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).